TARGET case TARGET-10-PARVCG — Acute Lymphoblastic Leukemia - Phase II (TARGET-ALL-P2)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Lymphoid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/d55bc453-e7f7-5e3e-bcb6-83c588dcd0de

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 10 years; Vital status: Dead; Days to death: 1,339 days (3.7 years).

Diagnoses (1)
1. Acute lymphocytic leukemia: ICD-O-3 morphology code: 9835/3; ICD-10 code: C91.0; Tissue or organ of origin: Bone marrow; Classification of tumor: primary; Age at diagnosis: 10.0 years (3,659 days); Year of diagnosis: 2008; Days to last follow up: 1,339 days (3.7 years).
   Treatment given: Protocol identifier: AALL0232.

Follow-up (3 entries)
- Days to follow up: 1,305 days (3.6 years); Days to first event: 1,305 days (3.6 years); First event: Relapse.
- Days to follow up: 1,339 days (3.7 years); Progression or recurrence: Yes; Progression or recurrence anatomic site: Bone marrow; Year of follow up: 2011.
- Days to follow up: 1,339 days (3.7 years); Progression or recurrence: Yes; Progression or recurrence anatomic site: Nervous system, NOS.

Molecular and laboratory tests (laboratory values grouped by visit day)
- BCR–ABL1 fusion: Negative.
- ETV6–RUNX1 fusion (FISH): Positive.
- KMT2A rearrangement (FISH): Negative.
- TCF3–PBX1 translocation: Negative.
- Trisomy 10: Negative.
- Trisomy 4: Negative.
- Day 0: Leukocytes 93.4 ×10³/µL.
- Day 8: Bone Marrow blast count 46%; Minimal Residual Disease (Flow Cytometry) 0.13%.
- Day 15: Bone Marrow blast count 4%.
- Day 29: Bone Marrow blast count 1%; Minimal Residual Disease (Flow Cytometry) 0.0077%.

Biospecimens (2 samples)
- Sample TARGET-10-PARVCG-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
- Sample TARGET-10-PARVCG-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_Blast_Data_20230727.xlsx, for sample TARGET-10-PARVCG-09A-01D:
- Blast %: 93

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_ClinicalData_Phase_II_Validation_20230727.xlsx:
- Overall Survival Time in Days: 1339
- WBC at Diagnosis: 93.4
- CNS Status at Diagnosis: CNS 2b
- MRD Day 8: 0.13
- MRD Day 8 Sensitivity: 0.01
- MRD Day 29: 0.0077
- MRD Day 29 Sensitivity: 0.0077
- Bone Marrow Site of Relapse: Yes
- CNS Site of Relapse: Yes
- Testes Site of Relapse: No
- Other Site of Relapse: No
- ETV6 RUNX1 Fusion Status: Positive
- TRISOMY 4 10 Status: Negative
- MLL Status: Negative
- TCF3 PBX1 Status: Negative
- BCR ABL1 Status: Negative
- BMA Blasts Day 8: 46
- BMA Blasts Day 15: 4
- BMA Blasts Day 29: 1
- Karyotype: 46,X,-X,del(13)(q12q32),+16[3]/46,XX[14]
- Down Syndrome: No
- DNA Index: 1
- Cell of Origin: B Cell ALL
